Somatic mutation profile of tumor specimen TCGA-LN-A4A3-01A (aliquot TCGA-LN-A4A3-01A-11D-A27G-09) from TCGA case TCGA-LN-A4A3, project TCGA-ESCA (Esophageal Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Middle third of esophagus; AJCC pathologic stage: Stage III; Tumor grade: G2; Age at diagnosis: 61.1 years (22,313 days).
Specimen TCGA-LN-A4A3-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2f271827-88b7-43f6-af98-89240eeb193c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-LN-A4A3-10A (Blood Derived Normal), aliquot TCGA-LN-A4A3-10A-01D-A27G-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/652ca534-8ede-4179-9f20-e62cf0c698b0

The open-access MAF lists 61 somatic variants for this specimen: 49 protein-altering or splice-affecting, 10 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 46, Silent 10, Frame Shift Ins 1, 3'Flank 1, Nonsense Mutation 1, Splice Site 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.880G>T p.E294* | Nonsense Mutation (SNP) | VAF 161/360 reads (45%) | hotspot (GDC flag); catalogued as rs1057520607, CM144128, COSV52689734, COSV52701760, COSV52773998, COSV53851434; ClinVar: pathogenic; called by muse, mutect2, varscan2
- CELSR1 | c.5620G>A p.D1874N | Missense Mutation (SNP) | VAF 18/92 reads (20%) | SIFT tolerated (0.65); PolyPhen benign (0.003); catalogued as rs141922879, COSV53093771; called by muse, mutect2, varscan2
- CHD7 | c.5410G>A p.E1804K | Missense Mutation (SNP) | VAF 7/72 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV71107832; called by muse, mutect2, varscan2
- CHRD | c.2732G>A p.R911Q | Missense Mutation (SNP) | VAF 30/71 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs372347094; called by muse, mutect2, varscan2
- EID2 | c.533G>A p.R178H | Missense Mutation (SNP) | VAF 4/41 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as COSV66810915; called by muse, mutect2, varscan2
- ELAC2 | c.1981G>C p.V661L | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT tolerated (0.61); PolyPhen benign (0.014); catalogued as rs747446525; called by muse, mutect2, varscan2
- ENPEP | c.161C>T p.A54V | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT tolerated (0.16); PolyPhen benign (0.043); catalogued as rs200528408, COSV54449792; called by muse, mutect2, varscan2
- EPHA5 | c.2549T>G p.I850R | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56650766; called by muse, mutect2, varscan2
- GCN1 | c.7400A>G p.Q2467R | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT tolerated (0.63); PolyPhen benign (0.001); catalogued as rs1239977541; called by muse, mutect2, varscan2
- H2BC21 | c.191A>G p.N64S | Missense Mutation (SNP) | VAF 8/196 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.813); catalogued as rs1446260534; called by muse, mutect2
- HDAC9 | c.890C>T p.T297I | Missense Mutation (SNP) | VAF 22/120 reads (18%) | SIFT tolerated (0.25); PolyPhen benign (0.157); catalogued as rs1399136414; called by muse, mutect2, varscan2
- IGF2R | c.2660C>T p.T887M | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs752875889; called by muse, mutect2, varscan2
- KCNH6 | c.1367G>A p.G456D | Missense Mutation (SNP) | VAF 9/83 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs1284368619; called by muse, mutect2, varscan2
- MID1 | c.1735C>T p.R579C | Missense Mutation (SNP) | VAF 10/16 reads (63%) | SIFT deleterious (0); PolyPhen possibly damaging (0.845); catalogued as rs770539991; called by muse, varscan2
- MKI67 | c.7868C>T p.T2623M | Missense Mutation (SNP) | VAF 32/120 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs368793936; called by muse, mutect2, varscan2
- MME | c.1858C>A p.Q620K | Missense Mutation (SNP) | VAF 9/83 reads (11%) | SIFT tolerated (0.36); PolyPhen benign (0.005); catalogued as COSV100852509; called by muse, mutect2, varscan2
- MTCL1 | c.4696C>T p.R1566W (on ENST00000306329 / NM_001378206.1; = p.R1247W on NM_015210.4) | Missense Mutation (SNP) | VAF 19/66 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs781057852, COSV60403389, COSV60410366; called by muse, mutect2, varscan2
- MUC4 | c.12803C>T p.P4268L (on ENST00000463781 / NM_018406.7; = p.P32L on NM_004532.6) | Missense Mutation (SNP) | VAF 23/108 reads (21%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.003); catalogued as rs142178516, COSV100203565; called by muse, mutect2, varscan2
- NEB | c.10613G>A p.R3538Q | Missense Mutation (SNP) | VAF 15/117 reads (13%) | SIFT tolerated (0.16); PolyPhen benign (0.047); catalogued as rs747898598, COSV51446102; called by muse, mutect2, varscan2
- OBSCN | c.7319G>A p.R2440Q | Missense Mutation (SNP) | VAF 15/197 reads (8%) | SIFT tolerated (0.47); PolyPhen possibly damaging (0.895); catalogued as rs547478529, COSV52836584; called by muse, mutect2
- RASGRF2 | c.1385G>A p.R462H | Missense Mutation (SNP) | VAF 4/29 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); catalogued as rs1329580753, COSV54126312; called by mutect2, varscan2
- RIPK4 | c.481G>T p.D161Y | Missense Mutation (SNP) | VAF 25/55 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1383464294; called by muse, mutect2, varscan2
- SPG21 | c.369C>A p.H123Q | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT tolerated (0.3); PolyPhen benign (0.109); catalogued as COSV52603851; called by muse, mutect2, varscan2
- TFPI | c.585T>A p.N195K | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.55); catalogued as rs890858430; called by muse, mutect2, varscan2
- ADAMTS3 | c.2311G>C p.E771Q | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.826); called by muse, mutect2
- ADCY8 | c.1590G>C p.W530C | Missense Mutation (SNP) | VAF 16/88 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.716); called by muse, mutect2
- ADHFE1 | c.1252G>C p.D418H | Missense Mutation (SNP) | VAF 19/61 reads (31%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- ALG10 | c.1250A>G p.Y417C | Missense Mutation (SNP) | VAF 14/105 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ANO5 | c.2483T>C p.V828A | Missense Mutation (SNP) | VAF 9/80 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.676); called by muse, mutect2, varscan2
- APAF1 | c.3725A>G p.Y1242C (on ENST00000551964 / NM_181861.2; = p.Y1188C on NM_001160.3) | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- C10orf90 | c.1191C>A p.S397R | Missense Mutation (SNP) | VAF 29/129 reads (22%) | SIFT tolerated (0.34); PolyPhen benign (0.057); called by muse, mutect2, varscan2
- CCT6B | c.1535C>T p.A512V | Missense Mutation (SNP) | VAF 33/87 reads (38%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.571); called by muse, mutect2, varscan2
- CDH11 | c.1760C>T p.T587I | Missense Mutation (SNP) | VAF 7/63 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.847); called by muse, mutect2, varscan2
- COPE | c.905T>C p.L302P | Missense Mutation (SNP) | VAF 14/148 reads (9%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.491); called by muse, mutect2
- ELOVL1 | c.259A>T p.S87C | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.852); called by muse, mutect2, varscan2
- FRMPD3 | c.962C>T p.T321I | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.78); called by muse, varscan2
- GAS2L2 | c.916C>A p.Q306K | Missense Mutation (SNP) | VAF 13/68 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); called by muse, mutect2, varscan2
- GDF2 | c.937A>T p.T313S | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- KHDC4 | c.1016A>G p.Y339C | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.263); called by muse, mutect2, varscan2
- MYO1C | c.1697T>C p.L566P (on ENST00000648651 / NM_001080779.2; = p.L531P on NM_033375.5) | Missense Mutation (SNP) | VAF 20/46 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- NFE2L3 | c.1951G>A p.D651N | Missense Mutation (SNP) | VAF 15/69 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- OR51V1 | c.752T>C p.V251A | Missense Mutation (SNP) | VAF 5/63 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.803); called by muse, mutect2
- SMG1 | c.5956G>A p.D1986N | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.984); called by muse, mutect2
- TMPRSS4 | c.190T>A p.C64S | Missense Mutation (SNP) | VAF 26/90 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.748); called by muse, mutect2, varscan2
- TNS2 | c.2057C>A p.A686D (on ENST00000314250 / NM_170754.4; = p.A696D on NM_015319.2) | Missense Mutation (SNP) | VAF 9/65 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- UBN1 | c.1592T>G p.L531R | Missense Mutation (SNP) | VAF 28/76 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- ZFP36L2 | c.502_503dup p.K169Afs*19 | Frame Shift Ins (INS) | VAF 10/95 reads (11%) | called by mutect2, pindel, varscan2
- ZNF341 | c.2035+2T>A p.X679_splice (on ENST00000375200 / NM_001282935.1; = p.X672_splice on NM_032819.4) | Splice Site (SNP) | VAF 24/56 reads (43%) | called by muse, mutect2, varscan2
- ZNF582 | c.976T>G p.L326V | Missense Mutation (SNP) | VAF 3/34 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2
- C3 | c.3321G>A p.L1107= | Silent (SNP) | VAF 13/47 reads (28%) | called by muse, mutect2, varscan2
- CTBP1 | c.861G>A p.A287= | Silent (SNP) | VAF 16/249 reads (6%) | catalogued as rs766411525; called by muse, mutect2
- F2 | c.1554G>A p.G518= | Silent (SNP) | VAF 24/54 reads (44%) | called by muse, mutect2, varscan2
- GLI3 | c.4608C>T p.S1536= | Silent (SNP) | VAF 24/71 reads (34%) | catalogued as rs776279429, COSV101229736; called by muse, mutect2, varscan2
- KCNQ2 | c.1575C>T p.C525= (on ENST00000359125 / NM_172107.4; = p.C497= on NM_004518.6) | Silent (SNP) | VAF 63/127 reads (50%) | catalogued as rs528539094, COSV60547827; called by muse, mutect2, varscan2
- PPRC1 | c.3210G>T p.V1070= | Silent (SNP) | VAF 6/18 reads (33%) | called by muse, mutect2, varscan2
- RPS14 | c.42C>A p.V14= | Silent (SNP) | VAF 18/45 reads (40%) | called by muse, mutect2, varscan2
- SLC7A5 | c.1410C>G p.P470= | Silent (SNP) | VAF 17/65 reads (26%) | catalogued as rs778987531, COSV55365569; called by muse, mutect2, varscan2
- TMF1 | c.1854G>A p.E618= | Silent (SNP) | VAF 4/22 reads (18%) | called by muse, mutect2
- TRAPPC9 | c.3336A>T p.G1112= | Silent (SNP) | VAF 20/80 reads (25%) | called by muse, mutect2, varscan2
- DGCR2 | c.625+2375A>T | Intron (SNP) | VAF 3/36 reads (8%) | called by muse, mutect2
- ZSCAN32 | chr16:3383044 C>T | 3'Flank (SNP) | VAF 8/148 reads (5%) | catalogued as COSV100514520; called by muse, mutect2
